Somatic mutation profile of tumor specimen TCGA-G6-A8L7-01A (aliquot TCGA-G6-A8L7-01A-11D-A36X-10) from TCGA case TCGA-G6-A8L7, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 81.8 years (29,883 days).
Specimen TCGA-G6-A8L7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afb536b1-02e5-4b87-b09d-4442852f78b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G6-A8L7-10A (Blood Derived Normal), aliquot TCGA-G6-A8L7-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba5968c3-892b-48eb-90c7-6d82bf315984

The open-access MAF lists 75 somatic variants for this specimen: 56 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 17, Frame Shift Del 10, Splice Site 4, Nonsense Mutation 4, RNA 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC1 | c.1998-2A>G p.X666_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | catalogued as rs1057518217, CS052418, COSV100052184; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABTB2 | c.2698-1G>A p.X900_splice | Splice Site (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100131771; called by muse, mutect2, varscan2
- ALYREF | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV100485876; called by muse, mutect2, varscan2
- ARHGAP26 | c.1569G>T p.M523I | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99191225; called by muse, mutect2, varscan2
- BRWD3 | c.1268A>C p.K423T | Missense Mutation (SNP) | VAF 112/562 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100956303; called by muse, mutect2, varscan2
- C2CD2L | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs201072240, COSV60883992; called by muse, mutect2, varscan2
- CCDC142 | c.194del p.E65Gfs*58 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as COSV99282312; called by mutect2, pindel, varscan2
- CNTNAP2 | c.1715C>G p.T572R | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100668586; called by muse, mutect2, varscan2
- COL13A1 | c.1505G>A p.R502H (on ENST00000398978 / NM_001130103.2; = p.R445H on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371347973; called by muse, mutect2, varscan2
- CREBRF | c.1689A>C p.L563F | Missense Mutation (SNP) | VAF 91/368 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99756097; called by muse, varscan2
- DDHD1 | c.1988A>G p.E663G (on ENST00000323669; = p.E860G on NM_030637.3) | Missense Mutation (SNP) | VAF 79/321 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV100079794; called by muse, mutect2, varscan2
- ECE2 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV100668724; called by muse, mutect2, varscan2
- EML5 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100715960; called by muse, mutect2, varscan2
- FAAH | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 19/59 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs779136084, COSV99680143; called by muse, mutect2, varscan2
- GABBR1 | c.2311+1G>T p.X771_splice | Splice Site (SNP) | VAF 22/80 reads (28%) | catalogued as COSV63544519; called by muse, mutect2, varscan2
- GDF5 | c.191del p.S64Tfs*23 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as COSV65499059; called by mutect2, varscan2
- HUWE1 | c.3144A>T p.Q1048H | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.845); catalogued as COSV99473276; called by muse, mutect2, varscan2
- IP6K3 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV99539991; called by muse, mutect2, varscan2
- IQCK | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774998510, COSV99575260; called by muse, mutect2, varscan2
- KALRN | c.5669A>C p.E1890A (on ENST00000360013 / NM_001024660.4; = p.E193A on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV99362509; called by muse, mutect2
- KSR2 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100350148; called by muse, mutect2, varscan2
- LPO | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs762108651, COSV99229109; called by muse, mutect2, varscan2
- MEGF8 | c.685A>C p.I229L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.195); catalogued as COSV99237874; called by muse, mutect2, varscan2
- MORF4L1 | c.311A>G p.Y104C (on ENST00000331268 / NM_206839.2; = p.Y65C on NM_006791.4) | Missense Mutation (SNP) | VAF 15/521 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV100489163; called by muse, mutect2
- MYH7 | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759579652, CM1412221, COSV100806354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAM2 | c.2377G>T p.E793* | Nonsense Mutation (SNP) | VAF 17/106 reads (16%) | catalogued as COSV99524104; called by muse, mutect2, varscan2
- NCAN | c.1561G>T p.E521* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as COSV99387826; called by muse, mutect2, varscan2
- NCKAP5 | c.4963C>T p.L1655F | Missense Mutation (SNP) | VAF 76/382 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as COSV100493385; called by muse, mutect2, varscan2
- NLRC4 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1271902433, COSV100707460; called by muse, mutect2, varscan2
- NOS1AP | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV100723481; called by muse, mutect2, varscan2
- NOS2 | c.3373G>T p.E1125* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100569780, COSV58223434; called by muse, mutect2, varscan2
- NYNRIN | c.2515T>G p.W839G | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV101230644; called by muse, mutect2, varscan2
- PGGT1B | c.522T>A p.F174L | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99685991; called by muse, mutect2, varscan2
- PKHD1L1 | c.4256G>A p.G1419E | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101006594; called by muse, varscan2
- PLXNA1 | c.4096C>T p.H1366Y | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.53); catalogued as COSV99303662; called by muse, mutect2, varscan2
- PRKAG1 | c.454A>G p.R152G | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100305298; called by muse, varscan2
- PRKDC | c.3373C>T p.Q1125* | Nonsense Mutation (SNP) | VAF 25/97 reads (26%) | catalogued as COSV100041679; called by muse, mutect2, varscan2
- RAB37 | c.155T>G p.F52C | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100463258; called by muse, mutect2, varscan2
- ROS1 | c.2399A>G p.Y800C | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV100877435; called by muse, mutect2, varscan2
- SDR16C5 | c.348del p.G117Afs*6 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | catalogued as COSV58127289; called by mutect2, pindel, varscan2
- SOS2 | c.2557A>G p.I853V | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99366459; called by muse, mutect2, varscan2
- TAOK3 | c.1423C>G p.L475V | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101183636; called by muse, mutect2
- UNC13B | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV101036954; called by muse, mutect2, varscan2
- WIPF3 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV54211098; called by muse, mutect2, varscan2
- YTHDC2 | c.3182T>C p.L1061S | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99363615; called by muse, mutect2, varscan2
- ZNF423 | c.532T>A p.Y178N (on ENST00000563137 / NM_001379286.1; = p.Y170N on NM_015069.4) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99282768; called by muse, mutect2, varscan2
- ZNF521 | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100832813; called by muse, mutect2, varscan2
- ACAN | c.5522del p.P1841Lfs*10 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- DHPS | c.837_846delinsTCTGGGCG p.I280Lfs*33 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by pindel, varscan2*
- EPS15 | c.574_581del p.V192Cfs*20 | Frame Shift Del (DEL) | VAF 22/135 reads (16%) | called by mutect2, pindel, varscan2
- ERMAP | c.1189_1198del p.P397Mfs*10 | Frame Shift Del (DEL) | VAF 39/276 reads (14%) | called by mutect2, pindel, varscan2
- HMGCS2 | c.482dup p.D161Efs*44 | Frame Shift Ins (INS) | VAF 29/131 reads (22%) | called by mutect2, pindel, varscan2
- HSD17B4 | c.2059del p.A687Lfs*7 (on ENST00000414835 / NM_001199291.3; = p.A662Lfs*7 on NM_000414.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3217del p.I1073Lfs*86 (on ENST00000296302 / NM_001366071.2; = p.I1048Lfs*86 on NM_018313.5) | Frame Shift Del (DEL) | VAF 23/94 reads (24%) | called by mutect2, pindel, varscan2
- PHTF1 | c.77del p.K26Sfs*11 | Frame Shift Del (DEL) | VAF 38/205 reads (19%) | called by pindel, varscan2
- QPCTL | c.1004-3_1004-2del p.X335_splice | Splice Site (DEL) | VAF 21/102 reads (21%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.2049G>T p.G683= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as COSV101001988; called by muse, mutect2, varscan2
- APBA1 | c.2403C>T p.H801= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs142971150; called by muse, mutect2
- BCL9L | c.3798G>T p.L1266= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99419696; called by muse, mutect2, varscan2
- CCDC105 | c.1092T>C p.C364= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99480003; called by muse, mutect2, varscan2
- FANCD2 | c.630C>T p.D210= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV99811889; called by muse, mutect2, varscan2
- FAT2 | c.5343C>T p.N1781= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV99943609; called by muse, mutect2, varscan2
- GAREM1 | c.924C>A p.L308= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV99331036; called by muse, mutect2, varscan2
- KIF1B | c.5067T>A p.L1689= (on ENST00000377086 / NM_001365952.1; = p.L1643= on NM_015074.3) | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV99823789; called by muse, mutect2, varscan2
- MRS2 | c.867A>C p.A289= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as COSV99219045; called by muse, mutect2, varscan2
- MRTFA | c.2637G>T p.P879= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV99960540; called by muse, mutect2, varscan2
- PLCH2 | c.1506C>A p.L502= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99616744; called by muse, mutect2, varscan2
- PPFIA1 | c.1968G>A p.R656= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV99557797; called by muse, mutect2, varscan2
- SAAL1 | c.399T>C p.S133= | Silent (SNP) | VAF 67/264 reads (25%) | catalogued as rs902470633, COSV100253980; called by muse, mutect2, varscan2
- TBCCD1 | c.922C>A p.R308= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as COSV100112057; called by muse, mutect2, varscan2
- TGFA | c.57G>A p.A19= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs371384477, COSV54913430; called by muse, mutect2, varscan2
- ZFYVE1 | c.1473C>T p.S491= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV100606937; called by muse, mutect2, varscan2
- ZMYM2 | c.4011C>T p.S1337= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as COSV101243944; called by muse, mutect2
- DCHS2 | n.7636C>T | RNA (SNP) | VAF 34/134 reads (25%) | catalogued as rs77468185, COSV61777606; called by muse, mutect2, varscan2
- MORF4 | n.472_476del | RNA (DEL) | VAF 24/130 reads (18%) | catalogued as rs1007719295; called by pindel, varscan2
